Somatic mutation profile of tumor specimen TCGA-IG-A97H-01A (aliquot TCGA-IG-A97H-01A-11D-A387-09) from TCGA case TCGA-IG-A97H, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 36.0 years (13,166 days).
Specimen TCGA-IG-A97H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88965ea9-78b1-4311-9260-4781e879d4fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A97H-10A (Blood Derived Normal), aliquot TCGA-IG-A97H-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61ff98ee-3036-4182-bdb6-42dad0ec55e1

The open-access MAF lists 101 somatic variants for this specimen: 79 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 18, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 2, Splice Site 2, RNA 2, Intron 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- ACCSL | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs749322101, COSV101122186; called by muse, mutect2, varscan2
- ASB6 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as rs1417984831; called by muse, mutect2
- ASPG | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs749790590, COSV71933650; called by muse, mutect2, varscan2
- ASRGL1 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs533515407; called by muse, mutect2, varscan2
- CRISP3 | c.541G>A p.V181I (on ENST00000371159 / NM_001368123.1; = p.V163I on NM_006061.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.075); catalogued as rs377483373, COSV99539129; called by muse, mutect2, varscan2
- DNHD1 | c.11456T>C p.I3819T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs747679287; called by muse, mutect2, varscan2
- ETNPPL | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs917918165; called by muse, mutect2, varscan2
- FLG | c.6856C>T p.H2286Y | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs770039879; called by muse, mutect2
- FLT3 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 25/36 reads (69%) | catalogued as COSV54047633; called by muse, mutect2, varscan2
- FLVCR2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV53163886; called by muse, mutect2, varscan2
- KRTAP13-4 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1246686240, COSV61878811; called by muse, mutect2, varscan2
- LEMD3 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as CM104377, COSV57650926; called by muse, mutect2, varscan2
- MECOM | c.2468del p.S823Cfs*46 (on ENST00000468789 / NM_001105078.4; = p.S1011Cfs*46 on NM_004991.4) | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | catalogued as COSV52961560; called by mutect2, pindel, varscan2
- MGA | c.5822C>G p.S1941C (on ENST00000219905 / NM_001164273.1; = p.S1732C on NM_001080541.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54957143, COSV54962154; called by muse, mutect2, varscan2
- MUC15 | c.119A>C p.K40T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99846680; called by muse, mutect2, varscan2
- MUC16 | c.20534C>T p.T6845I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs780491549; called by muse, mutect2, varscan2
- P2RY14 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs368040389; called by muse, mutect2
- PHKA1 | c.3622G>A p.A1208T | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs782814716, COSV100263603; called by muse, mutect2, varscan2
- PRKCB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs771388864; called by muse, varscan2
- PTPN22 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1184468706, COSV100703913; called by muse, mutect2, varscan2
- QDPR | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV55550272; called by muse, mutect2, varscan2
- RUNX1T1 | c.1402G>A p.V468M (on ENST00000265814 / NM_001198628.1; = p.V441M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV56143586; called by muse, mutect2, varscan2
- SEC14L2 | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs748368938; called by muse, varscan2
- SNCG | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs371074090; called by muse, mutect2, varscan2
- WDR18 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV52122204; called by muse, mutect2, varscan2
- XPO6 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV58965485; called by muse, mutect2, varscan2
- ZC3H10 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV57770282, COSV99072843; called by muse, mutect2, varscan2
- ABHD5 | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADCY2 | c.3058A>T p.I1020F | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFTPH | c.2122_2130del p.I708_D710del | In Frame Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- AGRN | c.5860C>G p.R1954G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- AMPD2 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- APLNR | c.377A>C p.D126A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BSDC1 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, varscan2
- CAPN13 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCDC39 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CKAP5 | c.5954_5955insTGCT p.R1986Afs*16 (on ENST00000529230 / NM_001008938.4; = p.R1926Afs*16 on NM_014756.3) | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CROT | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1G2 | c.113_115del p.G38del | In Frame Del (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- DDX19B | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DDX5 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DEPDC1 | c.1799A>G p.D600G (on ENST00000456315 / NM_001114120.3; = p.D316G on NM_017779.6) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, varscan2
- DGKK | c.1294T>C p.W432R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK9 | c.2668G>T p.V890L (on ENST00000376460 / NM_001366676.2; = p.V891L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EIF1AY | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EIF5B | c.246G>A p.K82= | Splice Region (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- FIGN | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR88 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HIPK2 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPG2 | c.1564T>C p.S522P | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KHDRBS2 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF21A | c.4194dup p.T1399Yfs*13 (on ENST00000361418 / NM_001378440.1; = p.T1386Yfs*13 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- KIF5B | c.793del p.I265Ffs*18 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- KNL1 | c.2074A>G p.I692V (on ENST00000346991 / NM_170589.5; = p.I666V on NM_144508.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LGI2 | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MED14 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC5AC | c.16291C>T p.P5431S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NPVF | c.525T>A p.D175E | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NUF2 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NUTM1 | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PADI6 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- PCDHA4 | c.1895G>A p.S632N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PCLO | c.6526G>A p.V2176I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDE3A | c.2722A>G p.T908A | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL1 | c.2812G>T p.D938Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- RBBP6 | c.4301T>A p.L1434Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RBM15 | c.1904G>A p.S635N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RGS7 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SIRPG | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SKIL | c.1968G>T p.Q656H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SLC9A6 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.417); called by muse, mutect2
- TOP3A | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBG2 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- UBQLN4 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UGT3A1 | c.689del p.P230Qfs*13 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- UNC13A | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- UNC13A | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VPS13D | c.9728del p.P3243Lfs*8 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.2910C>G p.L970= (on ENST00000616178 / NM_001291722.2; = p.L945= on NM_014376.4) | Silent (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- GNB1L | c.228G>A p.T76= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs368294430; called by muse, mutect2, varscan2
- GRWD1 | c.1326C>T p.R442= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs745453359; called by muse, varscan2
- HPS5 | c.732G>A p.R244= (on ENST00000349215 / NM_181507.2; = p.R130= on NM_007216.4) | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ICE1 | c.3229A>C p.R1077= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- IFNA4 | c.417C>T p.S139= | Silent (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- ING5 | c.672A>G p.K224= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs1439788450; called by muse, mutect2, varscan2
- MBLAC2 | c.9G>A p.A3= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- MMP27 | c.1488C>T p.S496= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52781188; called by muse, mutect2, varscan2
- RASSF7 | c.309G>A p.P103= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs770196669; called by muse, mutect2, varscan2
- SAMSN1 | c.492C>T p.F164= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs1480064173, COSV53467013; called by muse, mutect2, varscan2
- SPATA31E1 | c.4278G>T p.S1426= | Silent (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- TBC1D23 | c.1518C>T p.I506= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs748159443, COSV61369502; called by muse, mutect2, varscan2
- TNFRSF10D | c.285C>T p.A95= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- TRIOBP | c.4191G>A p.R1397= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- TRIP11 | c.3996A>T p.A1332= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- XRCC1 | c.1116G>A p.Q372= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- ZNF623 | c.1398A>G p.K466= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1323C>G | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.669A>C | RNA (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- NECTIN2 | c.1042+3850dup | Intron (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- SNORD116-24 | n.56A>T | RNA (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
